Somatic mutation profile of tumor specimen HCM-BROD-0120-C15-06A (aliquot HCM-BROD-0120-C15-06A-11D-A786-36) from HCMI case HCM-BROD-0120-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2; Age at diagnosis: 46.6 years (17,010 days).
Specimen HCM-BROD-0120-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a86a03c2-7061-4e73-847f-dda75baeff2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0120-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0120-C15-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae6be482-6931-46b4-aff7-624f5fe2d102

The open-access MAF lists 104 somatic variants for this specimen: 77 protein-altering or splice-affecting, 18 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 18, Intron 4, 5'Flank 2, 5'UTR 1, Nonsense Mutation 1, In Frame Del 1, 3'Flank 1, Splice Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMH4 | c.2181C>A p.F727L | Missense Mutation (SNP) | VAF 11/317 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99957540; called by muse, mutect2
- BRF1 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); catalogued as rs749231735; called by muse, mutect2, varscan2
- CBFA2T3 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs749297800, COSV51923475; called by muse, mutect2, varscan2
- CCDC63 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as rs1176913932; called by muse, mutect2
- CUL7 | c.4492C>T p.L1498F | Missense Mutation (SNP) | VAF 83/679 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1294277576, COSV54818108; called by muse, mutect2, varscan2
- DAGLB | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs760935184; called by muse, mutect2, varscan2
- DDX23 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100339612, COSV57286056; called by muse, mutect2
- DNAH3 | c.4576G>A p.A1526T | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.041); catalogued as rs778679316, COSV54502367; called by muse, mutect2, varscan2
- EIF4E | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs772918368, COSV99794595; called by muse, mutect2
- EPB41L1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 43/355 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52443391; called by muse, mutect2, varscan2
- EPHA1 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766796352, COSV51975121; called by muse, varscan2
- FBXL7 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as COSV61647313; called by muse, varscan2
- FLG | c.6982G>C p.E2328Q | Missense Mutation (SNP) | VAF 50/742 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs762998429, COSV64250003; called by muse, mutect2
- FOXI1 | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs749136856; called by muse, mutect2
- GLS | c.1397A>G p.Y466C | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100290696; called by muse, mutect2, varscan2
- GNPDA1 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1054193183, COSV60942726; called by muse, mutect2
- GPRC6A | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs201413211, COSV59952444; called by muse, mutect2, varscan2
- GRIN3B | c.2804G>A p.R935H | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1287022184; called by muse, varscan2
- HGF | c.1993G>A p.G665R | Missense Mutation (SNP) | VAF 29/459 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV99738789; called by muse, mutect2
- IQCF1 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1261110904; called by muse, mutect2, varscan2
- KLHL14 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs767060763, COSV100808696; called by muse, mutect2, varscan2
- KRT17 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 35/632 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs780251083, COSV100245050; called by muse, mutect2
- LARP6 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs1368682123; called by muse, mutect2, varscan2
- MAGEC3 | c.866G>A p.C289Y | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV53575965; called by muse, mutect2
- MEPCE | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 26/938 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52769332; called by muse, mutect2
- MGAT5B | c.2104G>A p.D702N (on ENST00000569840 / NM_001199172.2; = p.D700N on NM_144677.3) | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as rs201168609; called by muse, mutect2
- MRPL13 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.185); catalogued as rs1340922650; called by muse, mutect2, varscan2
- MYCBPAP | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs146029360; called by muse, mutect2, varscan2
- MYT1L | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 55/436 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs774259529, COSV101221538; called by muse, mutect2, varscan2
- NUP188 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs753037635, COSV65363346; called by muse, mutect2, varscan2
- OR5D14 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs771163642, COSV59455316; called by muse, mutect2
- PLIN4 | c.1937C>T p.A646V (on ENST00000301286; = p.A661V on NM_001367868.2) | Missense Mutation (SNP) | VAF 174/534 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs762835863, COSV56690988; called by muse, mutect2, varscan2
- RARA | c.247C>G p.R83G | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54190236; called by muse, mutect2, varscan2
- RYR1 | c.3124G>A p.V1042M | Missense Mutation (SNP) | VAF 59/320 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs540088339; called by muse, mutect2, varscan2
- SETD1B | c.194del p.V65Gfs*41 | Frame Shift Del (DEL) | VAF 41/164 reads (25%) | catalogued as COSV57349674; called by mutect2, pindel, varscan2
- SIDT1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs200970930; called by muse, mutect2
- TENM3 | c.5830C>T p.R1944W | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs955811797; called by muse, mutect2
- TENM3 | c.7523G>A p.R2508H | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1328986770; called by muse, mutect2, varscan2
- TNKS2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV65415016; called by muse, mutect2
- TRIM15 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.398); catalogued as rs746569348; called by muse, mutect2, varscan2
- TRPM3 | c.2683G>A p.V895M (on ENST00000357533 / NM_001366142.2; = p.V738M on NM_020952.6) | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs749397001; called by muse, mutect2, varscan2
- UHRF1BP1 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768149677; called by muse, mutect2, varscan2
- ZNF646 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs929304428; called by muse, mutect2
- ZSCAN5A | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs550648749, COSV54225211; called by muse, mutect2
- AGA | c.187_189del p.M63del | In Frame Del (DEL) | VAF 51/220 reads (23%) | called by mutect2, pindel, varscan2
- AP1G2 | c.238T>G p.F80V | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ARHGAP27 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 189/480 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BRINP3 | c.1752G>C p.W584C | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- CHD9 | c.1868A>C p.Q623P | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CRHBP | c.409T>C p.Y137H | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC5 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 24/486 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by muse, mutect2
- FOXC2 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.108); called by muse, mutect2
- KCNB1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); called by muse, mutect2
- KCNT2 | c.1736A>T p.Y579F | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- KIF27 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP2 | c.8940C>A p.D2980E | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP3K21 | c.1962A>C p.L654F | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.615); called by muse, varscan2
- MAU2 | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2
- MTOR | c.3865C>G p.L1289V | Missense Mutation (SNP) | VAF 16/297 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MUC5AC | c.16585+2T>G p.X5529_splice | Splice Site (SNP) | VAF 14/249 reads (6%) | called by muse, mutect2
- NLRP2 | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PRRX1 | c.440C>G p.A147G | Missense Mutation (SNP) | VAF 19/375 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PSMA8 | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PTPRN2 | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RICTOR | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SAG | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SCN2A | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC2A4 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 83/585 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SPTLC2 | c.875T>G p.L292W | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STARD9 | c.1697T>C p.I566T | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- THEGL | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 51/277 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- TMEM131L | c.1595G>A p.W532* | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.2434G>T p.A812S (on ENST00000591111; = p.A766S on NM_003319.4) | Missense Mutation (SNP) | VAF 18/248 reads (7%) | PolyPhen benign (0.04); called by muse, mutect2
- VSIG1 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2
- ZMYND12 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2
- ZNF121 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF415 | c.401C>A p.S134Y | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- ABCC12 | c.759G>A p.A253= | Silent (SNP) | VAF 19/191 reads (10%) | catalogued as rs778359631, COSV60912543; called by muse, mutect2, varscan2
- ADHFE1 | c.957C>T p.I319= | Silent (SNP) | VAF 43/336 reads (13%) | catalogued as rs768261247; called by muse, mutect2, varscan2
- BTN3A1 | c.1356A>G p.K452= | Silent (SNP) | VAF 74/297 reads (25%) | called by muse, mutect2, varscan2
- CNMD | c.111G>A p.A37= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1408851901, COSV65034028; called by muse, mutect2, varscan2
- DISP2 | c.2460G>A p.R820= | Silent (SNP) | VAF 23/444 reads (5%) | called by muse, mutect2
- DOCK2 | c.2097C>T p.Y699= | Silent (SNP) | VAF 35/305 reads (11%) | catalogued as rs1322913885; called by muse, mutect2, varscan2
- DSCAM | c.2919C>T p.N973= | Silent (SNP) | VAF 42/446 reads (9%) | catalogued as rs200413358, COSV101259586; called by muse, mutect2
- GPR151 | c.399C>G p.A133= | Silent (SNP) | VAF 48/187 reads (26%) | called by muse, mutect2, varscan2
- HEG1 | c.1875G>A p.S625= | Silent (SNP) | VAF 22/442 reads (5%) | catalogued as rs373718985; called by muse, mutect2
- HMCN2 | c.15075C>T p.R5025= | Silent (SNP) | VAF 34/237 reads (14%) | called by muse, mutect2, varscan2
- HSPG2 | c.11313G>A p.L3771= | Silent (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- IRX1 | c.1050G>A p.A350= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as rs1445451035; called by muse, mutect2
- KLHL4 | c.1437T>C p.Y479= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as rs1461340187; called by muse, mutect2, varscan2
- RAB22A | c.528C>T p.G176= | Silent (SNP) | VAF 40/214 reads (19%) | catalogued as rs758247390, COSV54832762; called by muse, mutect2, varscan2
- TARBP1 | c.249C>A p.G83= | Silent (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- THSD4 | c.591C>A p.R197= | Silent (SNP) | VAF 85/425 reads (20%) | called by muse, mutect2, varscan2
- TTC38 | c.396A>G p.E132= | Silent (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- ZFP28 | c.750G>A p.K250= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as COSV56735719; called by muse, mutect2
- ALDH2 | c.*26C>T | 3'UTR (SNP) | VAF 61/233 reads (26%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11345C>T | Intron (SNP) | VAF 16/458 reads (3%) | catalogued as COSV57127577; called by muse, mutect2
- NTN5 | chr19:48673185 G>A | 5'Flank (SNP) | VAF 30/216 reads (14%) | catalogued as rs764972111; called by muse, mutect2, varscan2
- PACRGL | c.-7G>A | 5'UTR (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- RARG | c.185-4274T>C | Intron (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- RNF170 | chr8:42850833 G>A | 3'Flank (SNP) | VAF 80/394 reads (20%) | called by muse, mutect2, varscan2
- RPL7P3 | chr20:62570579 A>G | 5'Flank (SNP) | VAF 25/536 reads (5%) | catalogued as rs1555904362; called by muse, mutect2
- WDR61 | c.12+85A>C | Intron (SNP) | VAF 20/153 reads (13%) | called by muse, varscan2
- ZNF76 | c.432+228C>T | Intron (SNP) | VAF 48/328 reads (15%) | called by muse, mutect2, varscan2
